Somatic mutation profile of tumor specimen C3L-06935-01 (aliquot CPT0393580006) from CPTAC case C3L-06935, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G4; Age at diagnosis: 56.5 years (20,623 days).
Specimen C3L-06935-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d27ca4d-4ab8-44f9-b143-edcf26461355.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06935-31 (Blood Derived Normal), aliquot CPT0390840002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2fa4629-a8db-4fbf-a5d4-9a2cec21324c

The open-access MAF lists 230 somatic variants for this specimen: 164 protein-altering or splice-affecting, 58 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 145, Silent 58, Nonsense Mutation 9, Frame Shift Del 4, Intron 4, Frame Shift Ins 2, 5'UTR 2, In Frame Ins 2, Splice Site 1, 3'Flank 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAI2 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 97/278 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137853227, COSV56492718; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NOTCH2 | c.7165C>T p.Q2389* | Nonsense Mutation (SNP) | VAF 140/420 reads (33%) | catalogued as rs387906749, CM120074; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RFXANK | c.232C>T p.R78* | Nonsense Mutation (SNP) | VAF 138/240 reads (58%) | catalogued as rs779699696, COSV99365200; ClinVar: pathogenic; called by muse, varscan2
- AHNAK | c.6368A>G p.D2123G | Missense Mutation (SNP) | VAF 54/564 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs778507792; called by muse, mutect2, varscan2
- AMBRA1 | c.2638G>A p.V880M (on ENST00000458649 / NM_001367468.1; = p.V790M on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/221 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as rs377069728; called by muse, mutect2, varscan2
- BCR | c.207C>G p.S69R | Missense Mutation (SNP) | VAF 83/264 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.728); catalogued as rs746660501; called by muse, mutect2, varscan2
- C9orf131 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 121/421 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs151113460; called by muse, mutect2, varscan2
- CASZ1 | c.1133T>C p.V378A | Missense Mutation (SNP) | VAF 185/493 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.513); catalogued as COSV100681024, COSV100682248; called by muse, mutect2, varscan2
- CCDC62 | c.1817T>G p.L606* | Nonsense Mutation (SNP) | VAF 62/221 reads (28%) | catalogued as rs1156834714; called by muse, mutect2, varscan2
- CD99L2 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 130/662 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs781819862, COSV100692602; called by muse, mutect2, varscan2
- CDH20 | c.2011G>A p.G671S | Missense Mutation (SNP) | VAF 111/393 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs928327481, COSV53017874; called by muse, mutect2, varscan2
- CDRT15 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 46/360 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs565675301, COSV69755434; called by muse, mutect2, varscan2
- CHD1 | c.4016A>T p.N1339I | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV52341001; called by muse, mutect2, varscan2
- CSMD3 | c.2564C>T p.S855L (on ENST00000297405 / NM_001363185.1; = p.S751L on NM_052900.3) | Missense Mutation (SNP) | VAF 79/254 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99827036; called by muse, mutect2, varscan2
- DUSP16 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 90/301 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs372330415; called by muse, mutect2, varscan2
- EDEM1 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 213/618 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs995993204; called by muse, mutect2, varscan2
- F8 | c.6492T>G p.I2164M | Missense Mutation (SNP) | VAF 201/451 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1286131283; called by muse, mutect2, varscan2
- FHDC1 | c.2906C>T p.P969L | Missense Mutation (SNP) | VAF 153/453 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV52597558; called by muse, mutect2, varscan2
- FOSL2 | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 165/566 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as rs577454302, COSV53103401; called by muse, mutect2, varscan2
- FSIP2 | c.6500T>C p.L2167P | Missense Mutation (SNP) | VAF 30/260 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs1364284012; called by muse, mutect2
- GIN1 | c.1065A>C p.K355N | Missense Mutation (SNP) | VAF 58/222 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV101204313; called by muse, mutect2, varscan2
- GOSR1 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 16/342 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1162437457, COSV56719986; called by muse, mutect2
- H3C2 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.364); catalogued as rs756571457; called by muse, mutect2, varscan2
- IGLL5 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 138/442 reads (31%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.007); catalogued as rs575661811, COSV73248955, COSV73249336; called by muse, varscan2
- IGLL5 | c.172A>G p.S58G | Missense Mutation (SNP) | VAF 120/340 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs779353676, COSV73250237, COSV73250743; called by muse, varscan2
- IGLL5 | c.181T>C p.S61P | Missense Mutation (SNP) | VAF 107/308 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs939720182; called by muse, varscan2
- IL4 | c.408C>A p.F136L | Missense Mutation (SNP) | VAF 9/288 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.303); catalogued as COSV51503556; called by muse, mutect2
- KIF13A | c.656G>A p.S219N | Missense Mutation (SNP) | VAF 99/322 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs944453104; called by muse, mutect2, varscan2
- KLHL21 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 430/605 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as rs1263534557; called by muse, mutect2, varscan2
- KMT2D | c.14747del p.P4916Rfs*79 | Frame Shift Del (DEL) | VAF 88/313 reads (28%) | catalogued as COSV56468393; called by mutect2, pindel, varscan2
- LRP2 | c.12512T>G p.L4171R | Missense Mutation (SNP) | VAF 110/283 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99788224; called by muse, mutect2, varscan2
- LTB | c.199C>G p.Q67E | Missense Mutation (SNP) | VAF 157/456 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.027); catalogued as rs189982676, COSV59865148; called by muse, mutect2, varscan2
- LUZP2 | c.978dup p.A327Sfs*10 | Frame Shift Ins (INS) | VAF 62/238 reads (26%) | catalogued as rs758762049; called by mutect2, pindel, varscan2
- MAGEL2 | c.2663A>G p.K888R | Missense Mutation (SNP) | VAF 134/430 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); catalogued as COSV58567406; called by muse, mutect2, varscan2
- MGAT4D | c.728T>C p.L243P | Missense Mutation (SNP) | VAF 65/216 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1365351342; called by muse, mutect2
- MYBPC3 | c.1101G>T p.K367N | Missense Mutation (SNP) | VAF 109/279 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs753209030; called by muse, mutect2, varscan2
- NEK9 | c.347A>G p.N116S | Missense Mutation (SNP) | VAF 63/210 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV99464518; called by muse, mutect2, varscan2
- NFKBIE | c.759_762del p.Y254Sfs*13 (on ENST00000275015; = p.Y115Sfs*13 on NM_004556.3) | Frame Shift Del (DEL) | VAF 144/271 reads (53%) | catalogued as rs755160004; called by mutect2, pindel, varscan2
- NOL9 | c.355G>C p.V119L | Missense Mutation (SNP) | VAF 350/507 reads (69%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV60228859; called by muse, mutect2, varscan2
- OR51E2 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 96/309 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs757545384, COSV101211322, COSV101211398; called by muse, varscan2
- P2RY8 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 263/459 reads (57%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.671); catalogued as COSV101184172, COSV67176674; called by muse, mutect2, varscan2
- PABPC4L | c.173T>A p.F58Y | Missense Mutation (SNP) | VAF 94/261 reads (36%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV69930285; called by muse, mutect2, varscan2
- PCLO | c.4084G>A p.D1362N | Missense Mutation (SNP) | VAF 72/250 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1199765167; called by muse, mutect2, varscan2
- PLPPR4 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 49/345 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs1320127846, COSV64568536; called by muse, mutect2, varscan2
- PNPLA6 | c.3547C>T p.R1183W (on ENST00000414982 / NM_001166111.2; = p.R1135W on NM_006702.5) | Missense Mutation (SNP) | VAF 134/402 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766389806, COSV55381353; called by muse, varscan2
- POU3F4 | c.275C>G p.A92G | Missense Mutation (SNP) | VAF 149/452 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV64537578, COSV64538737; called by muse, mutect2, varscan2
- PRODH2 | c.1013C>T p.P338L (on ENST00000301175; = p.P262L on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 151/452 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as rs182628111, COSV56560937, COSV99995404; called by muse, mutect2, varscan2
- RBBP6 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as rs753345674, COSV60505938; called by muse, mutect2, varscan2
- RBFOX2 | c.268G>A p.A90T (on ENST00000438146 / NM_001349995.2; = p.A20T on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/319 reads (29%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.003); catalogued as rs140420879, COSV53267536; called by muse, varscan2
- RNASE13 | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 118/366 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs146892669, COSV58794513; called by muse, mutect2
- RNF157 | c.1682C>T p.P561L | Missense Mutation (SNP) | VAF 106/273 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); catalogued as rs1344005107, COSV53944348; called by muse, mutect2, varscan2
- RPA4 | c.135C>A p.D45E | Missense Mutation (SNP) | VAF 78/440 reads (18%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs33970383; called by muse, mutect2, varscan2
- RPS6KA6 | c.1552C>T p.R518W | Missense Mutation (SNP) | VAF 87/244 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs200685475, COSV53116531, COSV53124777; called by muse, mutect2, varscan2
- SPTLC3 | c.1637C>T p.T546M | Missense Mutation (SNP) | VAF 59/218 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.506); catalogued as rs201373651, COSV100983167; called by muse, mutect2, varscan2
- TBL1XR1 | c.1183T>C p.Y395H | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1323521798, COSV70499467, COSV70501617; called by muse, mutect2, varscan2
- TBR1 | c.907G>T p.E303* | Nonsense Mutation (SNP) | VAF 42/258 reads (16%) | catalogued as rs1553510388, COSV101271393; called by muse, mutect2, varscan2
- TGFBR2 | c.1342T>C p.Y448H | Missense Mutation (SNP) | VAF 111/319 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM064330; called by muse, mutect2, varscan2
- TIGD1 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 16/416 reads (4%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.553); catalogued as rs1291721780; called by muse, mutect2
- TNMD | c.89A>C p.K30T | Missense Mutation (SNP) | VAF 165/371 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV65977426; called by muse, mutect2, varscan2
- TPST1 | c.1006G>A p.G336R | Missense Mutation (SNP) | VAF 84/253 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1316925305, COSV59178471; called by muse, mutect2, varscan2
- ZDHHC17 | c.1333C>T p.R445* | Nonsense Mutation (SNP) | VAF 176/318 reads (55%) | catalogued as COSV100602183; called by muse, mutect2, varscan2
- ACTBL2 | c.1079A>C p.K360T | Missense Mutation (SNP) | VAF 86/278 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ADH1C | c.327C>G p.S109R | Missense Mutation (SNP) | VAF 82/234 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- ALX1 | c.818G>T p.S273I | Missense Mutation (SNP) | VAF 298/503 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- ANGPT4 | c.448A>C p.T150P | Missense Mutation (SNP) | VAF 36/283 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- ANKRD17 | c.3473G>C p.C1158S | Missense Mutation (SNP) | VAF 9/297 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.033); called by muse, mutect2
- ASAP1 | c.2218T>C p.C740R | Missense Mutation (SNP) | VAF 100/284 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.93); called by muse, varscan2
- ASAP1 | c.2215T>C p.F739L | Missense Mutation (SNP) | VAF 95/276 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.637); called by muse, varscan2
- ASH1L | c.2587C>T p.Q863* | Nonsense Mutation (SNP) | VAF 47/540 reads (9%) | called by muse, mutect2
- ATG13 | c.1399T>C p.Y467H (on ENST00000359513 / NM_001346321.1; = p.Y430H on NM_014741.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 81/246 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BAZ2B | c.3167C>G p.A1056G | Missense Mutation (SNP) | VAF 78/274 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C2CD4B | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 163/516 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CACNA1E | c.964T>G p.L322V | Missense Mutation (SNP) | VAF 124/254 reads (49%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- CAMTA2 | c.374T>C p.V125A | Missense Mutation (SNP) | VAF 10/292 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- CATSPER3 | c.284C>A p.T95K | Missense Mutation (SNP) | VAF 75/247 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- CBLB | c.2289T>A p.Y763* | Nonsense Mutation (SNP) | VAF 74/135 reads (55%) | called by muse, mutect2, varscan2
- CDH9 | c.218A>C p.Y73S | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, varscan2
- CETP | c.476A>G p.D159G | Missense Mutation (SNP) | VAF 113/225 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CHRDL1 | c.1036T>A p.S346T (on ENST00000372045; = p.S352T on NM_145234.4) | Missense Mutation (SNP) | VAF 70/524 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CNGA2 | c.998T>G p.L333R | Missense Mutation (SNP) | VAF 123/541 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CNTN6 | c.2876C>T p.S959L | Missense Mutation (SNP) | VAF 69/220 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- COA8 | c.448A>C p.N150H | Missense Mutation (SNP) | VAF 78/223 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- CTNNA2 | c.593A>G p.K198R | Missense Mutation (SNP) | VAF 74/207 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CTR9 | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 64/216 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- CUX1 | c.3540G>C p.E1180D | Missense Mutation (SNP) | VAF 116/382 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DDX21 | c.906T>C p.F302= | Splice Region (SNP) | VAF 48/140 reads (34%) | called by muse, mutect2, varscan2
- DOCK11 | c.4961A>G p.H1654R | Missense Mutation (SNP) | VAF 72/317 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- EGR3 | c.154+1G>A p.X52_splice | Splice Site (SNP) | VAF 71/198 reads (36%) | called by muse, mutect2, varscan2
- EHD1 | c.14T>G p.V5G | Missense Mutation (SNP) | VAF 154/475 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- ELMO3 | c.1354C>T p.P452S (on ENST00000652269; = p.P399S on NM_024712.5) | Missense Mutation (SNP) | VAF 19/474 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- F11R | c.787C>T p.R263* | Nonsense Mutation (SNP) | VAF 151/308 reads (49%) | called by muse, mutect2, varscan2
- FAT4 | c.4899dup p.Y1634Ifs*22 | Frame Shift Ins (INS) | VAF 64/297 reads (22%) | called by mutect2, pindel, varscan2
- FILIP1L | c.2117A>C p.Q706P (on ENST00000354552 / NM_182909.3; = p.Q466P on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 96/274 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- FRMD7 | c.2139A>C p.L713F | Missense Mutation (SNP) | VAF 61/253 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- FSIP2 | c.11765T>G p.V3922G | Missense Mutation (SNP) | VAF 54/405 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- FSIP2 | c.12199A>C p.N4067H | Missense Mutation (SNP) | VAF 77/268 reads (29%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- FZD10 | c.148A>G p.T50A | Missense Mutation (SNP) | VAF 127/421 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GCNA | c.962A>C p.D321A | Missense Mutation (SNP) | VAF 104/368 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.29); called by muse, varscan2
- GNPTAB | c.3178del p.M1060Cfs*9 | Frame Shift Del (DEL) | VAF 82/255 reads (32%) | called by mutect2, pindel, varscan2
- GPRASP2 | c.2221A>C p.M741L | Missense Mutation (SNP) | VAF 96/435 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- H1-2 | c.267C>G p.S89R | Missense Mutation (SNP) | VAF 104/279 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- H1-5 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 107/385 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- H2AC6 | c.230C>G p.T77S | Missense Mutation (SNP) | VAF 118/342 reads (35%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- H3C13 | c.54G>T p.R18S | Missense Mutation (SNP) | VAF 113/438 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.074); called by mutect2, varscan2
- HSP90AB1 | c.322T>C p.S108P | Missense Mutation (SNP) | VAF 100/188 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSPG2 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 155/526 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- IFIT3 | c.965T>A p.L322H | Missense Mutation (SNP) | VAF 86/328 reads (26%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- IGHM | c.157A>T p.T53S | Missense Mutation (SNP) | VAF 123/214 reads (57%) | SIFT deleterious (0.02); called by muse, mutect2, varscan2
- IGHV1-69 | c.311G>C p.S104T | Missense Mutation (SNP) | VAF 73/159 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.259); called by muse, varscan2
- IGSF21 | c.169A>G p.I57V | Missense Mutation (SNP) | VAF 21/204 reads (10%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- IKZF3 | c.776T>C p.L259S | Missense Mutation (SNP) | VAF 74/281 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- IMPG1 | c.1136A>C p.E379A | Missense Mutation (SNP) | VAF 67/200 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KCNJ15 | c.815T>C p.L272P | Missense Mutation (SNP) | VAF 117/363 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KLHL31 | c.1395C>G p.D465E | Missense Mutation (SNP) | VAF 162/502 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- KLK7 | c.602G>A p.C201Y | Missense Mutation (SNP) | VAF 81/195 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LCA5 | c.475C>G p.Q159E | Missense Mutation (SNP) | VAF 100/310 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- LRRC42 | c.631A>T p.N211Y | Missense Mutation (SNP) | VAF 109/299 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- LRRC8C | c.590A>G p.N197S | Missense Mutation (SNP) | VAF 87/261 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MEOX2 | c.132_137dup p.S46_S47dup | In Frame Ins (INS) | VAF 54/387 reads (14%) | called by mutect2, varscan2
- MOB4 | c.218A>C p.H73P | Missense Mutation (SNP) | VAF 29/219 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- MOV10 | c.587A>C p.Y196S | Missense Mutation (SNP) | VAF 106/274 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- MSL2 | c.1519G>T p.E507* | Nonsense Mutation (SNP) | VAF 139/365 reads (38%) | called by muse, mutect2, varscan2
- MUC16 | c.28382T>C p.V9461A | Missense Mutation (SNP) | VAF 100/321 reads (31%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MYC | c.85_87dup p.E29dup (on ENST00000377970; = p.E44dup on NM_002467.6) | In Frame Ins (INS) | VAF 128/408 reads (31%) | called by mutect2, varscan2
- NAP1L2 | c.1218A>C p.L406F | Missense Mutation (SNP) | VAF 94/343 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NDUFV2 | c.479T>C p.V160A | Missense Mutation (SNP) | VAF 64/205 reads (31%) | SIFT tolerated (0.97); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NOLC1 | c.701A>G p.K234R | Missense Mutation (SNP) | VAF 136/420 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- NPAS1 | c.677C>T p.T226I | Missense Mutation (SNP) | VAF 115/379 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OLR1 | c.412G>T p.A138S | Missense Mutation (SNP) | VAF 63/226 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR10AC1 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 170/493 reads (34%) | SIFT deleterious, low confidence (0); called by muse, varscan2
- OR2F2 | c.760A>T p.T254S | Missense Mutation (SNP) | VAF 101/327 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- OR4N2 | c.92T>A p.V31D | Missense Mutation (SNP) | VAF 78/265 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.089); called by muse, varscan2
- OR5T3 | c.131T>G p.F44C | Missense Mutation (SNP) | VAF 18/414 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by muse, mutect2
- OR6K2 | c.647T>G p.F216C | Missense Mutation (SNP) | VAF 45/395 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- OSBPL10 | c.167G>A p.S56N | Missense Mutation (SNP) | VAF 202/615 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- PABPC5 | c.1008A>C p.E336D | Missense Mutation (SNP) | VAF 126/534 reads (24%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- PAX4 | c.554T>C p.L185P | Missense Mutation (SNP) | VAF 85/208 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PF4V1 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 59/218 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- PRDM1 | c.1805C>T p.P602L | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PXDNL | c.2620C>T p.P874S | Missense Mutation (SNP) | VAF 129/414 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RGPD4 | c.4013T>A p.V1338D | Missense Mutation (SNP) | VAF 110/377 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RRAGA | c.505C>T p.L169F | Missense Mutation (SNP) | VAF 97/269 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RRP1B | c.719G>A p.G240D | Missense Mutation (SNP) | VAF 99/335 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SACS | c.8062A>C p.T2688P | Missense Mutation (SNP) | VAF 111/358 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SASH1 | c.656A>G p.Q219R | Missense Mutation (SNP) | VAF 84/293 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SATL1 | c.171C>A p.S57R (on ENST00000395409; = p.S244R on NM_001012980.2) | Missense Mutation (SNP) | VAF 45/491 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.137); called by muse, mutect2
- SHE | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 79/340 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- SLC6A12 | c.905T>C p.L302P | Missense Mutation (SNP) | VAF 97/281 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLITRK6 | c.1864G>A p.V622I | Missense Mutation (SNP) | VAF 101/319 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SYVN1 | c.241T>C p.S81P | Missense Mutation (SNP) | VAF 124/335 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- TEX11 | c.2393del p.K798Rfs*36 (on ENST00000344304; = p.K783Rfs*36 on NM_031276.3) | Frame Shift Del (DEL) | VAF 61/261 reads (23%) | called by mutect2, pindel, varscan2
- TMSB4X | c.43A>G p.K15E | Missense Mutation (SNP) | VAF 75/154 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- TSKU | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 156/464 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, varscan2
- TTN | c.37879G>A p.E12627K (on ENST00000591111; = p.E5203K on NM_003319.4) | Missense Mutation (SNP) | VAF 136/407 reads (33%) | PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TTN | c.24050A>T p.Y8017F (on ENST00000591111; = p.Y7090F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/269 reads (28%) | PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- UBE2QL1 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 15/360 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.147); called by muse, mutect2
- UNC5C | c.5G>T p.R2M | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- VPS8 | c.1688A>G p.K563R (on ENST00000625842 / NM_001349294.1; = p.K561R on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 94/260 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- WRN | c.3292T>A p.L1098I | Missense Mutation (SNP) | VAF 52/159 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- ZC3H12B | c.2194C>A p.P732T | Missense Mutation (SNP) | VAF 131/476 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZFR | c.602A>G p.Y201C | Missense Mutation (SNP) | VAF 52/214 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZNF629 | c.290C>G p.P97R | Missense Mutation (SNP) | VAF 30/482 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2
- ZNF705D | c.761A>C p.K254T | Missense Mutation (SNP) | VAF 89/674 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- ZNF83 | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 79/258 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- ABLIM3 | c.339G>A p.K113= | Silent (SNP) | VAF 73/237 reads (31%) | called by muse, mutect2, varscan2
- ANKEF1 | c.573A>G p.E191= | Silent (SNP) | VAF 101/281 reads (36%) | called by muse, mutect2, varscan2
- APOBEC2 | c.216T>C p.Y72= | Silent (SNP) | VAF 119/372 reads (32%) | catalogued as rs1331464598; called by muse, mutect2, varscan2
- ARHGAP20 | c.3231T>G p.A1077= | Silent (SNP) | VAF 57/420 reads (14%) | called by muse, mutect2, varscan2
- ARHGAP25 | c.438C>T p.L146= (on ENST00000409202 / NM_001007231.3; = p.L139= on NM_014882.3) | Silent (SNP) | VAF 97/298 reads (33%) | called by muse, mutect2, varscan2
- ARHGAP29 | c.1207C>T p.L403= | Silent (SNP) | VAF 66/211 reads (31%) | called by muse, mutect2, varscan2
- BOLL | c.609C>G p.A203= | Silent (SNP) | VAF 39/135 reads (29%) | called by muse, mutect2, varscan2
- BTG1 | c.102G>A p.E34= | Silent (SNP) | VAF 118/351 reads (34%) | catalogued as rs773917016; called by muse, mutect2, varscan2
- BTG2 | c.96G>A p.E32= | Silent (SNP) | VAF 271/433 reads (63%) | catalogued as COSV51857365; called by muse, mutect2, varscan2
- C4orf54 | c.2424C>T p.F808= | Silent (SNP) | VAF 103/360 reads (29%) | catalogued as rs1321548390, COSV72766914; called by muse, mutect2, varscan2
- CACNA1C | c.3861C>T p.D1287= | Silent (SNP) | VAF 75/238 reads (32%) | catalogued as rs773917645; called by muse, mutect2, varscan2
- CAD | c.2943C>T p.T981= | Silent (SNP) | VAF 63/176 reads (36%) | catalogued as rs746689662, COSV53034008; called by muse, mutect2, varscan2
- CCDC168 | c.5340A>G p.R1780= | Silent (SNP) | VAF 42/280 reads (15%) | catalogued as rs564186986; called by muse, mutect2, varscan2
- CFAP94 | c.1851T>C p.C617= (on ENST00000320267 / NM_001352064.2; = p.C623= on NM_018272.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 88/241 reads (37%) | called by muse, mutect2, varscan2
- CTDP1 | c.2046G>A p.T682= | Silent (SNP) | VAF 58/453 reads (13%) | catalogued as rs756882272, COSV50003598; called by muse, varscan2
- DIAPH2 | c.21G>A p.A7= | Silent (SNP) | VAF 111/521 reads (21%) | catalogued as COSV61271100; called by muse, mutect2, varscan2
- DTX1 | c.43C>T p.L15= | Silent (SNP) | VAF 138/437 reads (32%) | catalogued as rs1263444536; called by muse, mutect2, varscan2
- EEF1A2 | c.1083C>T p.I361= | Silent (SNP) | VAF 120/362 reads (33%) | called by muse, varscan2
- FRMPD3 | c.1206T>C p.T402= | Silent (SNP) | VAF 80/334 reads (24%) | catalogued as rs1253502710; called by muse, varscan2
- GPRASP2 | c.1920C>T p.V640= | Silent (SNP) | VAF 117/456 reads (26%) | called by muse, mutect2, varscan2
- H1-2 | c.135C>T p.T45= | Silent (SNP) | VAF 106/311 reads (34%) | catalogued as rs150026047; called by muse, mutect2, varscan2
- H2AC12 | c.78C>T p.F26= | Silent (SNP) | VAF 122/329 reads (37%) | called by muse, mutect2, varscan2
- HSPD1 | c.198G>A p.Q66= | Silent (SNP) | VAF 31/237 reads (13%) | called by muse, mutect2, varscan2
- IGHV1-69 | c.183A>G p.G61= | Silent (SNP) | VAF 39/107 reads (36%) | catalogued as rs782364721; called by muse, mutect2, varscan2
- IGKV2-24 | c.237G>A p.R79= | Silent (SNP) | VAF 129/369 reads (35%) | catalogued as rs555236815; called by muse, mutect2, varscan2
- IGLV4-3 | c.228C>T p.S76= | Silent (SNP) | VAF 128/358 reads (36%) | catalogued as rs778331609; called by muse, mutect2, varscan2
- IRGQ | c.1488A>G p.P496= | Silent (SNP) | VAF 210/608 reads (35%) | called by mutect2, varscan2
- KCTD8 | c.744C>T p.F248= | Silent (SNP) | VAF 137/479 reads (29%) | catalogued as rs911454417, COSV63586187; called by muse, mutect2, varscan2
- KDM1B | c.1857T>C p.Y619= (on ENST00000449850; = p.Y386= on NM_153042.4) | Silent (SNP) | VAF 63/204 reads (31%) | called by muse, varscan2
- KIAA1549 | c.213C>T p.N71= | Silent (SNP) | VAF 79/243 reads (33%) | catalogued as rs779912686; called by muse, mutect2, varscan2
- KRTAP9-2 | c.352A>C p.R118= | Silent (SNP) | VAF 111/702 reads (16%) | called by muse, mutect2, varscan2
- LRRN3 | c.19C>A p.R7= | Silent (SNP) | VAF 54/186 reads (29%) | catalogued as COSV57817640; called by muse, mutect2, varscan2
- MBOAT7 | c.1005C>T p.S335= | Silent (SNP) | VAF 73/511 reads (14%) | catalogued as rs756804673, COSV99825162; called by muse, mutect2, varscan2
- MED12 | c.2193C>T p.H731= | Silent (SNP) | VAF 99/355 reads (28%) | called by muse, mutect2, varscan2
- MUC16 | c.14646T>G p.T4882= | Silent (SNP) | VAF 87/306 reads (28%) | called by muse, mutect2, varscan2
- OGT | c.2790C>T p.H930= | Silent (SNP) | VAF 98/399 reads (25%) | catalogued as rs137859805; called by muse, mutect2, varscan2
- PCLO | c.10548A>C p.I3516= | Silent (SNP) | VAF 109/325 reads (34%) | catalogued as COSV61619884; called by muse, mutect2, varscan2
- PIM1 | c.438C>T p.S146= | Silent (SNP) | VAF 166/483 reads (34%) | catalogued as COSV65164459, COSV65165150, COSV65166400; called by muse, mutect2, varscan2
- PLK2 | c.520A>C p.R174= | Silent (SNP) | VAF 82/217 reads (38%) | called by muse, mutect2, varscan2
- POSTN | c.798C>T p.D266= | Silent (SNP) | VAF 84/313 reads (27%) | catalogued as rs759253817, COSV101123470, COSV65712939; called by muse, mutect2, varscan2
- PPP6R1 | c.1113A>T p.A371= | Silent (SNP) | VAF 150/392 reads (38%) | called by muse, varscan2
- PWWP3B | c.1944A>C p.S648= | Silent (SNP) | VAF 78/373 reads (21%) | called by muse, mutect2, varscan2
- SCN8A | c.1959C>T p.G653= | Silent (SNP) | VAF 152/451 reads (34%) | called by muse, mutect2, varscan2
- SEPTIN6 | c.27G>A p.Q9= | Silent (SNP) | VAF 136/571 reads (24%) | called by muse, mutect2, varscan2
- SIAE | c.936G>A p.T312= | Silent (SNP) | VAF 89/319 reads (28%) | catalogued as rs538047865; called by muse, mutect2, varscan2
- SLC8A1 | c.432T>C p.S144= | Silent (SNP) | VAF 112/337 reads (33%) | called by muse, mutect2, varscan2
- SOWAHB | c.2190C>T p.P730= | Silent (SNP) | VAF 54/402 reads (13%) | called by muse, mutect2, varscan2
- SPECC1 | c.945A>C p.S315= | Silent (SNP) | VAF 89/282 reads (32%) | called by muse, mutect2, varscan2
- TFB1M | c.96G>A p.Q32= | Silent (SNP) | VAF 15/351 reads (4%) | called by muse, mutect2
- TLR10 | c.1512T>C p.S504= | Silent (SNP) | VAF 92/291 reads (32%) | called by muse, mutect2, varscan2
- TNPO1 | c.2199C>T p.C733= | Silent (SNP) | VAF 72/233 reads (31%) | called by muse, mutect2, varscan2
- TRAPPC10 | c.108G>C p.T36= | Silent (SNP) | VAF 92/258 reads (36%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.3483G>T p.L1161= | Silent (SNP) | VAF 93/337 reads (28%) | called by muse, mutect2, varscan2
- TTN | c.18210C>T p.I6070= (on ENST00000591111; = p.I5143= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 78/238 reads (33%) | catalogued as rs936677884, COSV59977700; called by muse, mutect2, varscan2
- VIM | c.453G>A p.E151= | Silent (SNP) | VAF 128/397 reads (32%) | called by muse, mutect2, varscan2
- VN1R4 | c.780T>C p.D260= | Silent (SNP) | VAF 52/296 reads (18%) | called by muse, mutect2, varscan2
- VTA1 | c.597T>C p.Y199= | Silent (SNP) | VAF 86/245 reads (35%) | catalogued as rs541725891; called by muse, mutect2, varscan2
- VWDE | c.2778T>C p.I926= | Silent (SNP) | VAF 48/166 reads (29%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73847552 A>C | 5'Flank (SNP) | VAF 49/172 reads (28%) | called by muse, mutect2, varscan2
- DNAAF3 | c.-12G>A | 5'UTR (SNP) | VAF 102/337 reads (30%) | called by muse, varscan2
- ETV1 | c.45+291T>C | Intron (SNP) | VAF 81/243 reads (33%) | called by muse, mutect2, varscan2
- IDO2 | chr8:40016190 G>A | 3'Flank (SNP) | VAF 41/151 reads (27%) | catalogued as rs552504572; called by muse, mutect2, varscan2
- PHF3 | c.-232G>A | 5'UTR (SNP) | VAF 100/288 reads (35%) | called by muse, varscan2
- SDCBP | c.-15-3229A>G | Intron (SNP) | VAF 55/154 reads (36%) | called by muse, mutect2, varscan2
- SLC12A6 | c.271+17788G>A | Intron (SNP) | VAF 39/298 reads (13%) | catalogued as rs200355116, COSV99271611; called by muse, mutect2, varscan2
- SRGAP1 | c.1539+533G>A | Intron (SNP) | VAF 65/398 reads (16%) | catalogued as rs763317209; called by muse, mutect2, varscan2
